Somatic mutation profile of tumor specimen MMRF_1589_1_BM_CD138pos (aliquot MMRF_1589_1_BM_CD138pos_T1_KBS5U_L04122) from MMRF case MMRF_1589, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.8 years (18,917 days).
Specimen MMRF_1589_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3458473-0c66-4bc2-903c-1056cfec56be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1589_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1589_1_PB_Whole_C2_KBS5U_L04128; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46dcda05-28d6-4859-887a-1daad90ab242

The open-access MAF lists 91 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 31, Missense Mutation 29, Intron 9, Silent 8, RNA 4, 3'Flank 2, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, In Frame Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- FAT4 | c.6172T>C p.Y2058H | Missense Mutation (SNP) | VAF 52/371 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV58707616; called by muse, mutect2, varscan2
- FCN2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs143090112; called by muse, mutect2, varscan2
- GABRA6 | c.452C>A p.T151N | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755056537; called by muse, mutect2, varscan2
- IGLV3-1 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs376569759; called by muse, mutect2, varscan2
- IGLV3-1 | c.314A>T p.Y105F | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as rs185803370; called by muse, varscan2
- KIAA1217 | c.4556C>T p.T1519I | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100287474; called by muse, mutect2, varscan2
- MAPK15 | c.167G>T p.R56I | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62029202; called by muse, mutect2
- OR2T6 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV63216855; called by muse, mutect2, varscan2
- OR52A1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs368837704; called by muse, mutect2, varscan2
- PRELID3B | c.496A>T p.K166* | Nonsense Mutation (SNP) | VAF 14/204 reads (7%) | catalogued as COSV54812581; called by muse, mutect2
- RBM10 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs868917893, COSV61307545; called by muse, mutect2
- RCOR1 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51772539, COSV99031474; called by muse, mutect2, varscan2
- SCN10A | c.5438G>A p.G1813E | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866518737, COSV71862060; called by muse, mutect2, varscan2
- SLC34A2 | c.575C>G p.T192R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as CM146500; called by muse, mutect2, varscan2
- SNTB2 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs199841622, COSV60350489; called by muse, mutect2, varscan2
- TOP3A | c.2605G>C p.A869P | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100329188; called by muse, mutect2, varscan2
- ADGRE1 | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- AFF2 | c.206A>C p.N69T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ANKK1 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC171 | c.1162A>G p.R388G | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2
- CPLANE1 | c.8030G>A p.W2677* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- KLHL24 | c.1638del p.Y547Ifs*29 | Frame Shift Del (DEL) | VAF 51/133 reads (38%) | called by mutect2, pindel, varscan2
- LENG9 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LRRC8E | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- LRRTM1 | c.614T>C p.F205S | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRNIP | c.127-2A>G p.X43_splice | Splice Site (SNP) | VAF 55/172 reads (32%) | called by muse, mutect2, varscan2
- MYH4 | c.30T>G p.F10L | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- NUDT6 | c.553+8T>C | Splice Region (SNP) | VAF 13/420 reads (3%) | called by muse, mutect2
- OR5A1 | c.544T>C p.C182R | Missense Mutation (SNP) | VAF 115/357 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF14 | c.1780C>G p.P594A | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- SOD3 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STK10 | c.1103_1105del p.P368_S369delinsR | In Frame Del (DEL) | VAF 23/112 reads (21%) | called by mutect2, pindel, varscan2
- TBK1 | c.1466A>T p.N489I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.177); called by muse, mutect2
- VPS28 | c.477G>C p.E159D | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XRCC6 | c.1553del p.L518Rfs*47 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | called by mutect2, pindel, varscan2
- BCL2L11 | c.561A>G p.L187= (on ENST00000393256 / NM_138621.5; = p.L127= on NM_006538.5) | Silent (SNP) | VAF 46/231 reads (20%) | called by muse, mutect2, varscan2
- BSND | c.162C>T p.C54= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs942451327; called by muse, mutect2, varscan2
- CRISPLD1 | c.78T>C p.V26= | Silent (SNP) | VAF 88/211 reads (42%) | called by muse, mutect2, varscan2
- FAM71C | c.27T>C p.Y9= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as rs1240458351; called by muse, mutect2
- LAMA1 | c.75C>T p.A25= | Silent (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- OTOG | c.801G>A p.S267= | Silent (SNP) | VAF 9/206 reads (4%) | catalogued as rs1183210896; called by muse, mutect2
- WSCD1 | c.1494G>A p.V498= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as rs1475148112; called by muse, mutect2, varscan2
- ZNF215 | c.582G>A p.L194= | Silent (SNP) | VAF 36/247 reads (15%) | catalogued as rs1431268595; called by muse, mutect2, varscan2
- AC109583.1 | c.-483+46T>C | Intron (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*1499A>T | 3'UTR (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- ANO5 | c.*3468C>T | 3'UTR (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- APBA2 | c.*508C>T | 3'UTR (SNP) | VAF 34/118 reads (29%) | catalogued as rs1023500772; called by muse, mutect2, varscan2
- ATP10D | c.*269T>A | 3'UTR (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- BCAR3 | c.358-21467T>C | Intron (SNP) | VAF 30/316 reads (9%) | called by muse, mutect2
- C18orf54 | c.*3041C>T | 3'UTR (SNP) | VAF 70/338 reads (21%) | called by muse, mutect2, varscan2
- C20orf202 | c.*127A>G | 3'UTR (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- CCDC14 | c.230+42T>C | Intron (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- CCND3 | c.199-392G>A | Intron (SNP) | VAF 282/489 reads (58%) | catalogued as rs750296016; called by muse, mutect2, varscan2
- CDC42 | c.*1260C>T | 3'UTR (SNP) | VAF 71/377 reads (19%) | called by muse, mutect2, varscan2
- CDH11 | c.*2629T>G | 3'UTR (SNP) | VAF 87/162 reads (54%) | called by muse, mutect2, varscan2
- CDIPT | c.332+61C>T | Intron (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2
- CNTN1 | c.*1741A>G | 3'UTR (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- DDX47 | chr12:12813307 T>G | 5'Flank (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- DIO2 | c.*2406G>A | 3'UTR (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- DST | c.4296+3990G>A | Intron (SNP) | VAF 236/257 reads (92%) | called by muse, mutect2, varscan2
- EHHADH | c.*1426G>A | 3'UTR (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- ENG | c.*418C>A | 3'UTR (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- FAM126A | c.*3729A>G | 3'UTR (SNP) | VAF 264/546 reads (48%) | called by muse, mutect2
- FAT3 | c.*2274dup | 3'UTR (INS) | VAF 122/198 reads (62%) | called by mutect2, varscan2
- GLIPR1L2 | c.*879C>A | 3'UTR (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- GPRC5B | c.*1918G>A | 3'UTR (SNP) | VAF 12/438 reads (3%) | called by muse, mutect2
- GRIP1 | c.*602G>A | 3'UTR (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- HDAC4 | c.*498G>A | 3'UTR (SNP) | VAF 27/62 reads (44%) | catalogued as rs1204678462; called by muse, mutect2, varscan2
- HINFP | c.*1380T>C | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- HPN-AS1 | n.175C>T | RNA (SNP) | VAF 28/247 reads (11%) | catalogued as rs780798669; called by muse, mutect2
- HSPA12A | c.*2350G>A | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- IRF4 | c.*1099_*1100del | 3'UTR (DEL) | VAF 18/138 reads (13%) | called by pindel, varscan2
- ITGA6 | chr2:172505724 G>A | 3'Flank (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- KIF2B | c.*60T>C | 3'UTR (SNP) | VAF 9/51 reads (18%) | catalogued as rs1033136864; called by muse, varscan2
- LZTS1 | c.*2807G>C | 3'UTR (SNP) | VAF 26/126 reads (21%) | catalogued as rs1180839111; called by muse, mutect2, varscan2
- MSRB1P1 | n.101G>T | RNA (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2, varscan2
- PACS1 | c.979-65T>C | Intron (SNP) | VAF 51/160 reads (32%) | called by muse, mutect2, varscan2
- PLPP3 | c.*729A>C | 3'UTR (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- PPP2R2A | c.*2171T>G | 3'UTR (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- SLC7A11 | c.*119T>A | 3'UTR (SNP) | VAF 164/328 reads (50%) | called by muse, mutect2, varscan2
- STAT5B | c.*1733T>G | 3'UTR (SNP) | VAF 15/104 reads (14%) | catalogued as rs1567651772; called by muse, mutect2, varscan2
- TBC1D3P2 | n.226C>A | RNA (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- TDGP1 | n.1107A>T | RNA (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- TRPM3 | chr9:70535450 C>T | 3'Flank (SNP) | VAF 179/599 reads (30%) | catalogued as COSV62579467; called by muse, mutect2, varscan2
- UBE2QL1 | c.*293G>A | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- ZNF274 | c.853-150C>T | Intron (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2
- ZNF493 | c.-132+10210G>C | Intron (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- ZNF516 | c.*3386C>T | 3'UTR (SNP) | VAF 35/151 reads (23%) | catalogued as rs1343975249; called by muse, mutect2, varscan2
- ZNF738 | c.*1290A>G | 3'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- ZNF765 | c.*766T>G | 3'UTR (SNP) | VAF 210/338 reads (62%) | called by muse, mutect2, varscan2
